Gene-level copy-number profile of tumor specimen HCM-BROD-0120-C15-06A from HCMI case HCM-BROD-0120-C15, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: female; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Esophagus, NOS; Tumor grade: G2; Age at diagnosis: 46.6 years (17,010 days).
Specimen HCM-BROD-0120-C15-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 529c711a-bfbe-4056-9f49-ec5042832d93.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HCM-BROD-0120-C15-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,225 have no estimate.
https://portal.gdc.cancer.gov/files/596496dd-3618-4a5b-8686-7b62ccad5b14

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 5; copy number 1: 2,363; copy number 2: 39,145; copy number 3: 13,813; copy number 4: 1,381; copy number 5: 372; copy number 6: 548; copy number 7: 202; copy number 8: 282; copy number 9: 104; copy number 10: 15; copy number 11: 47; copy number 12: 31; copy number 14: 16; copy number 15: 5; copy number 17: 18; copy number 20: 32; copy number 21: 1; copy number 22: 1; copy number 27: 2; copy number 51: 15.

Homozygous deletions (total copy number 0; autosomes only): 5 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:68,537,184–68,670,652, 5 genes (within-gene range 0–2): UGT2B17, AC147055.2, AC147055.4, AC147055.3, UGT2B15.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 1,691 genes in 27 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:37,611,350–43,285,617, 176 genes, copy number 5–12 (broad region; genes not listed).
- chr4:139,495,941–146,521,964, 107 genes, copy number 5–11 (broad region; genes not listed).
- chr4:153,034,211–153,415,081, 6 genes, copy number 6 (within-gene range 1–6): AC093599.1, TRIM2, AC013477.1, RNU6-1196P, Y_RNA, ANXA2P1.
- chr5:35,617,844–41,261,438, 91 genes, copy number 5–6 (broad region; genes not listed).
- chr6:55,327,469–55,940,624, 5 genes, copy number 5: GFRAL, HMGCLL1, AL590290.1, BMP5, NPM1P36.
- chr7:70,837,738–80,391,474, 210 genes, copy number 5–6 (within-gene range 4–6) (broad region; genes not listed).
- chr7:80,377,554–80,377,835, 1 gene, copy number 6 (within-gene range 4–6): SNRPBP1.
- chr7:98,877,933–99,050,831, 1 gene, copy number 7 (within-gene range 4–7): TRRAP.
- chr7:98,989,867–106,908,980, 254 genes, copy number 7–8 (broad region; genes not listed).
- chr7:108,470,417–112,206,407, 28 genes, copy number 8–9: PNPLA8, RPL7P32, THAP5, DNAJB9, AC005487.1, AC002487.1, C7orf66, AC004014.2, AC004014.1, BUB3P1, AC002386.1, AC073071.1, AC073387.1, AC073387.2, EIF3IP1, RPL3P8, AC073114.1, AC073114.2, IMMP2L, AC073326.1, LRRN3, AC003989.2, AC003989.1, DOCK4, AC003077.1, DOCK4-AS1, RNA5SP237, AC003080.1.
- chr8:34,784,028–34,874,633, 2 genes, copy number 5: LINC01288, AC087343.1.
- chr8:36,784,324–36,936,125, 1 gene, copy number 5 (within-gene range 4–5): KCNU1.
- chr8:36,887,456–39,105,445, 67 genes, copy number 5 (broad region; genes not listed).
- chr10:58,512,872–65,315,080, 69 genes, copy number 5–8 (broad region; genes not listed).
- chr11:100,641,975–105,531,697, 82 genes, copy number 5 (broad region; genes not listed).
- chr12:50,185,580–50,229,984, 3 genes, copy number 5: AC008147.2, AC008147.3, AC008147.1.
- chr12:50,326,230–50,396,622, 2 genes, copy number 5 (within-gene range 1–5): FAM186A, AC090058.1.
- chr12:50,504,985–51,515,763, 35 genes, copy number 9: DIP2B, RNU6-769P, RNU6-238P, Y_RNA, AC013244.1, ATF1, AC013244.2, RN7SL519P, TMPRSS12, AC013244.3, METTL7A, AC008121.2, Y_RNA, AC008121.1, HIGD1C, AC008121.3, SLC11A2, RNU6-87P, RNU6-1273P, LETMD1, CSRNP2, TFCP2, RPL35AP29, PHBP19, Y_RNA, RNU6-199P, POU6F1, AC139768.1, DAZAP2, SMAGP, BIN2, CELA1, GALNT6, SLC4A8, AC107031.1.
- chr12:66,347,431–70,637,440, 85 genes, copy number 5–8 (within-gene range 2–9) (broad region; genes not listed).
- chr13:37,534,940–38,066,444, 7 genes, copy number 5 (within-gene range 2–5): LINC00547, POSTN, TRPC4, RNA5SP26, AL356495.1, LINC02334, HSPD1P9.
- chr17:28,855,010–30,702,775, 91 genes, copy number 5–8 (within-gene range 3–8) (broad region; genes not listed).
- chr17:34,927,859–35,189,345, 16 genes, copy number 14 (within-gene range 2–14): CCT6B, AC022903.2, ZNF830, LIG3, RFFL, AC004223.3, AC004223.4, AC004223.2, AC004223.1, RAD51D, RNU6-840P, Vault, FNDC8, NLE1, UNC45B, AC022916.4.
- chr17:37,514,807–38,749,817, 40 genes, copy number 5–15 (within-gene range 3–15): SYNRG, AC243585.2, DDX52, MIR378J, AC243571.2, AC243585.1, HNF1B, AC243571.1, YWHAEP7, RNU6-489P, TBC1D3K, 5S_rRNA, TBC1D3L, TBC1D3D, TBC1D3C, AC233968.1, Y_RNA, TBC1D3E, RNA5SP526, TBC1D3, NPEPPSP1, Y_RNA, MRPL45, GPR179, SOCS7, ARHGAP23, AC244153.1, SRCIN1, AC006449.1, EPOP, MIR4734, AC006449.6, AC006449.2, MLLT6, AC006449.3, MIR4726, AC006449.7, CISD3, RNA5SP440, PCGF2.
- chr17:38,925,168–39,747,291, 35 genes, copy number 17–51: LINC00672, FBXO47, AC006441.2, AC006441.4, AC006441.5, LINC02079, LRRC37A11P, AC091178.1, RDM1P5, PLXDC1, AC091178.2, ARL5C, AC004408.2, AC004408.1, CACNB1, RPL19, STAC2, AC015910.1, FBXL20, AC005288.1, MED1, CDK12, RNU6-233P, AC009283.1, NEUROD2, AC087491.1, PPP1R1B, STARD3, TCAP, PNMT, PGAP3, ERBB2, MIR4728, MIEN1, GRB7.
- chr18:21,650,901–33,751,195, 190 genes, copy number 5–22 (broad region; genes not listed).
- chr20:21,085,576–23,990,454, 86 genes, copy number 6–7 (broad region; genes not listed).
- chr20:24,142,590–24,144,386, 1 gene, copy number 6: AL110503.1.

Autosomal genes at a single copy (total copy number 1): 2,363. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
